Gene-level copy-number profile of tumor specimen TCGA-61-1917-01A from TCGA case TCGA-61-1917, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 60.2 years (21,972 days).
Specimen TCGA-61-1917-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.570200ec-cb6e-48a2-8c86-612593ce4c76.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-1917-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 819 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/154940c0-a4f0-4d77-9174-78d11bfe951d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,755; copy number 2: 21,187; copy number 3: 18,453; copy number 4: 11,725; copy number 5: 2,860; copy number 6: 1,151; copy number 7: 529; copy number 8: 144.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-61-1917-01): tumor purity 0.84, ploidy 3.03, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,684 genes in 36 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:155,335,268–156,033,342, 34 genes, copy number 6 (within-gene range 3–6): ASH1L, MIR555, RNU6-106P, ASH1L-IT1, RNU6-1297P, POU5F1P4, ASH1L-AS1, AL353807.4, DAP3P1, AL353807.1, AL353807.2, MSTO1, AL353807.3, AL353807.5, YY1AP1, DAP3, AL162734.1, MSTO2P, GON4L, AL139128.1, SYT11, U4, RIT1, KHDC4, SNORA80E, SCARNA4, SCARNA4, RXFP4, ARHGEF2, MIR6738, AL355388.1, ARHGEF2-AS1, AL355388.2, SSR2.
- chr1:225,401,502–226,090,465, 23 genes, copy number 5: LBR, LINC02765, AC092811.1, ENAH, AC099066.2, AC099066.1, RNU6-1304P, SRP9, AC099066.3, EPHX1, AL591895.1, TMEM63A, LEFTY1, AL117348.2, PYCR2, MIR6741, AL117348.1, LEFTY2, NDUFA3P3, SDE2, AL512343.2, H3-3A, LINC01703.
- chr1:226,870,184–244,944,216, 406 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr1:245,673,732–248,919,946, 137 genes, copy number 5 (broad region; genes not listed).
- chr2:38,814–416,885, 10 genes, copy number 5 (within-gene range 2–5): FAM110C, AC079779.1, SH3YL1, ACP1, ALKAL2, AC079779.2, AC079779.3, AC079779.4, LINC01865, AC105393.2.
- chr2:113,107,214–113,627,090, 20 genes, copy number 6 (within-gene range 4–6): IL1RN, PSD4, AC016683.1, PAX8-AS1, PAX8, AC016745.1, IGKV1OR2-108, AC016745.2, CBWD2, FOXD4L1, LINC01961, PGM5P4-AS1, PGM5P4, FAM138B, AL078621.2, MIR1302-3, WASH2P, DDX11L2, AL078621.1, RPL23AP7.
- chr2:127,638,381–128,318,868, 25 genes, copy number 5 (within-gene range 4–5): LIMS2, GPR17, WDR33, SFT2D3, RNY4P7, Y_RNA, ZFP91P1, POLR2D, RNU6-395P, RPS26P19, Metazoa_SRP, AMMECR1L, AC012306.2, AC012306.3, AC012306.1, SAP130, AC108059.2, Y_RNA, UGGT1, SRMP3, AC108059.1, DYNLT3P2, RPL14P6, RPL21P34, HS6ST1.
- chr2:217,693,895–219,236,679, 71 genes, copy number 5 (broad region; genes not listed).
- chr3:112,302,478–113,287,459, 23 genes, copy number 5 (within-gene range 4–5): AC112487.1, AC112487.2, CD200, AC092894.1, BTLA, OR7E100P, AC092692.1, ATG3, SLC35A5, CCDC80, AC048334.1, LINC02042, CD200R1L-AS1, CD200R1L, CD200R1, AC074044.1, GTPBP8, NEPRO, AC078785.1, AC078785.3, AC078785.2, LINC02044, BOC.
- chr3:145,523,538–146,606,216, 18 genes, copy number 5: LARP7P4, GM2AP1, RPL21P39, AC055758.2, AC055758.1, AC107021.2, AC107021.1, LNCSRLR, PLOD2, PLSCR4, AC130509.1, AC069528.1, PLSCR2, AC069528.2, PLSCR1, RNU6-428P, PLSCR5, PLSCR5-AS1.
- chr3:169,083,499–198,222,513, 588 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr5:58,198–8,794,197, 183 genes, copy number 5 (broad region; genes not listed).
- chr5:14,143,342–17,670,571, 86 genes, copy number 5 (broad region; genes not listed).
- chr6:167,607–9,294,133, 181 genes, copy number 5 (broad region; genes not listed).
- chr6:86,432,244–86,436,138, 2 genes, copy number 5: AL391417.1, RN7SL643P.
- chr6:151,088,103–151,228,447, 1 gene, copy number 7 (within-gene range 3–7): AL138733.1.
- chr6:151,196,681–151,621,193, 14 genes, copy number 7: AL138733.2, RNU6-300P, AL356535.1, AKAP12, RNU6-1247P, RNY4P20, RN7SKP268, ZBTB2, Y_RNA, RMND1, HSPA8P15, ARMT1, CCDC170, RNU6-813P.
- chr6:151,813,276–151,814,179, 1 gene, copy number 7: AL356311.1.
- chr10:628,638–13,668,445, 232 genes, copy number 6–7 (broad region; genes not listed).
- chr10:13,675,646–13,871,175, 5 genes, copy number 6: AL157392.4, AL157392.1, RNA5SP301, AL157392.2, NUTF2P5.
- chr10:16,207,821–26,212,532, 148 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr11:64,555,690–88,176,593, 716 genes, copy number 5–7 (broad region; genes not listed).
- chr12:5,948,877–6,238,271, 5 genes, copy number 6: VWF, RN7SL69P, AC005845.1, CD9, Y_RNA.
- chr12:6,786,858–21,501,669, 415 genes, copy number 5 (broad region; genes not listed).
- chr13:51,921,251–52,334,277, 13 genes, copy number 6 (within-gene range 3–6): AL162377.2, ATP7B, FABP5P2, ALG11, UTP14C, NEK5, AL139082.1, NEK3, MRPS31P5, AL158066.1, THSD1P1, AL158066.2, TPTE2P2.
- chr13:74,231,457–114,337,626, 515 genes, copy number 6–7 (broad region; genes not listed).
- chr14:18,333,726–21,351,301, 177 genes, copy number 6 (broad region; genes not listed).
- chr16:11,249,619–11,976,643, 32 genes, copy number 5 (within-gene range 3–5): RMI2, TNP2, PRM3, AC009121.1, PRM2, PRM1, AC009121.4, MIR548H2, Y_RNA, AC009121.3, AC009121.2, AC099489.1, AC099489.2, AC099489.3, LITAF, SNN, TXNDC11, AC007613.1, ZC3H7A, Metazoa_SRP, AC010654.1, BCAR4, RSL1D1, AC007216.4, GSPT1, AC007216.3, COX6CP1, AC007216.2, AC007216.5, NPIPB2, TNFRSF17, UBL5P4.
- chr16:11,976,851–11,977,850, 1 gene, copy number 5: AC007216.1.
- chr18:3,653,030–3,656,282, 1 gene, copy number 6: AP002478.1.
- chr18:26,348,347–52,339,025, 348 genes, copy number 5 (broad region; genes not listed).
- chr18:52,409,042–52,419,644, 2 genes, copy number 5: AC011155.1, VN1R76P.
- chr19:9,019,344–9,163,424, 8 genes, copy number 6 (within-gene range 3–6): BOLA3P2, OR1M4P, OR1M1, OR7G2, OR7G1, OR7G15P, OR7G3, ZNF317.
- chr20:50,794,894–62,841,159, 230 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr21:14,961,235–15,065,936, 1 gene, copy number 5 (within-gene range 3–5): NRIP1.
- chr21:14,971,470–15,696,581, 12 genes, copy number 5–7 (within-gene range 3–7): AF127577.2, AF127577.6, AF127577.5, AF222684.1, AF222685.1, AF130248.1, AF246928.1, AJ009632.2, CYCSP42, AJ009632.1, RNU6-1326P, RAD23BP3.

Autosomal genes at a single copy (total copy number 1): 2,970. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
